Somatic mutation profile of tumor specimen MMRF_2539_2_BM_CD138pos (aliquot MMRF_2539_2_BM_CD138pos_T1_KHS5U_L12892) from MMRF case MMRF_2539, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.8 years (18,918 days).
Specimen MMRF_2539_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31b6761d-c2a6-4fc3-9ca7-20dec5b68a19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2539_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2539_1_PB_Whole_C3_KHS5U_K15140; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43c5fe12-a97c-4f59-8b17-0869ba518dd5

The open-access MAF lists 76 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 29, Missense Mutation 20, Silent 10, Intron 7, 5'Flank 2, Splice Site 2, 5'UTR 2, 3'Flank 1, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 69/173 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763931319; called by muse, mutect2, varscan2
- CARMIL1 | c.2717G>A p.R906H | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs1260860195, COSV61515627; called by muse, mutect2, varscan2
- DRD1 | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1184464458; called by muse, mutect2, varscan2
- FBXL17 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as COSV62861254; called by muse, mutect2, varscan2
- FSTL5 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as rs776031059, COSV60209083; called by muse, mutect2, varscan2
- IGHV2-70 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.453); catalogued as rs373474286; called by muse, varscan2
- IGLL5 | c.206+2T>G p.X69_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as rs561122720, COSV73250168, COSV73251186; called by muse, mutect2, varscan2
- IGLV3-1 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs375057861; called by muse, mutect2, varscan2
- KANK1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs900068781; called by muse, mutect2
- MEGF6 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs762307115; called by muse, mutect2
- PLCE1 | c.6064C>G p.P2022A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.833); catalogued as COSV53362255; called by muse, mutect2, varscan2
- PLIN4 | c.3751C>T p.R1251W (on ENST00000301286; = p.R1266W on NM_001367868.2) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.625); catalogued as rs542288285, COSV56681306; called by muse, mutect2, varscan2
- SREBF2 | c.1301C>A p.P434Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63331285; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1253C>G p.P418R | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AQP11 | c.126_137delinsA p.V43Lfs*81 | Frame Shift Del (DEL) | VAF 41/245 reads (17%) | called by pindel, varscan2*
- ATM | c.7089+1_7089+5del p.X2363_splice | Splice Site (DEL) | VAF 110/239 reads (46%) | called by mutect2, pindel, varscan2
- CPVL | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ELFN1 | c.2351G>C p.R784P | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIBADH | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IGHV5-51 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX5L | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAPGEF2 | c.4330A>G p.T1444A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIPA1L1 | c.411_425del p.N137_N141del | In Frame Del (DEL) | VAF 41/153 reads (27%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1797C>A p.H599Q | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AP3B2 | c.1308T>C p.C436= | Silent (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- BMPR1A | c.879G>A p.A293= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs770203548; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHX15 | c.1873C>T p.L625= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- LTBP4 | c.405A>T p.L135= (on ENST00000308370 / NM_001042544.1; = p.L98= on NM_003573.2) | Silent (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- OR13C2 | c.345G>T p.L115= | Silent (SNP) | VAF 66/398 reads (17%) | called by muse, mutect2, varscan2
- OR5AR1 | c.735T>C p.L245= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs1430062076; called by muse, mutect2, varscan2
- SLC13A5 | c.858C>T p.G286= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs754297638; called by muse, mutect2, varscan2
- SNX14 | c.1242C>T p.F414= (on ENST00000314673 / NM_001350535.1; = p.F370= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- UBA3 | c.547C>T p.L183= | Silent (SNP) | VAF 38/161 reads (24%) | called by muse, mutect2, varscan2
- VNN3 | c.780G>A p.E260= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as rs1304715203; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+29605T>G | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- AP003548.1 | n.336-487C>A | Intron (SNP) | VAF 62/257 reads (24%) | called by muse, mutect2, varscan2
- ARCN1 | c.*1020T>A | 3'UTR (SNP) | VAF 103/690 reads (15%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+2977C>T | Intron (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
- CACNA1I | c.6027+383T>C | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- CALHM5 | c.*4595C>A | 3'UTR (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- CLTC | c.*1040G>T | 3'UTR (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- COL12A1 | c.*2010G>A | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- CPOX | c.*989C>G | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- CYYR1 | c.*299A>G | 3'UTR (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- FOXF2 | c.*53G>A | 3'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- FUT3 | c.*115C>T | 3'UTR (SNP) | VAF 3/32 reads (9%) | catalogued as rs1315396504, COSV99744546; called by muse, mutect2
- GABRG1 | c.*3507C>T | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- GALNT13 | c.*1145C>A | 3'UTR (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- GLTPP1 | chr11:18188955 G>A | 5'Flank (SNP) | VAF 26/124 reads (21%) | catalogued as rs939418070; called by muse, mutect2, varscan2
- GPR132 | c.*5A>G | 3'UTR (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- GRAMD1A | chr19:34996111 G>A | 5'Flank (SNP) | VAF 42/136 reads (31%) | catalogued as rs530320130, COSV100526349; called by muse, varscan2
- HAO1 | c.*577C>A | 3'UTR (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2
- HERPUD1 | c.906-99T>G | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
- KCNK3 | c.*4393C>A | 3'UTR (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- KRTAP4-8 | c.*460C>A | 3'UTR (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2
- MBTD1 | c.*2283_*2284del | 3'UTR (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- MBTPS1 | c.*672C>T | 3'UTR (SNP) | VAF 10/46 reads (22%) | catalogued as rs558793609; called by muse, mutect2, varscan2
- MON1A | c.1670+19G>C | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1565C>A | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- NUDT15 | c.*66G>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- NUP155 | c.*88G>A | 3'UTR (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- PHETA2 | c.*474T>A | 3'UTR (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- PRMT2 | c.-24T>A | 5'UTR (SNP) | VAF 76/333 reads (23%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.-350T>C | 5'UTR (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- RAD23B | c.*1613G>A | 3'UTR (SNP) | VAF 7/14 reads (50%) | catalogued as rs1204590535; called by muse, mutect2, varscan2
- SGMS2 | chr4:107912611 G>A | 3'Flank (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- SHF | c.303+75C>T | Intron (SNP) | VAF 16/81 reads (20%) | catalogued as rs772231758; called by muse, mutect2, varscan2
- SLC6A5 | c.*1884T>C | 3'UTR (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- SOX11 | c.*1845T>G | 3'UTR (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- TIMP3 | c.*2483C>T | 3'UTR (SNP) | VAF 11/68 reads (16%) | catalogued as rs1455892418; called by muse, mutect2, varscan2
- TRAK2 | c.*1745C>G | 3'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- UBE3A | c.*1331T>G | 3'UTR (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- WFDC3 | c.*113C>A | 3'UTR (SNP) | VAF 24/97 reads (25%) | catalogued as COSV99714685; called by muse, mutect2, varscan2
- ZNF33A | c.*579T>G | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- ZNF780A | c.*812G>A | 3'UTR (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
